Surgical pathology report (de-identified scan), TCGA case TCGA-23-2079, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-2079-01A (Primary Tumor).

[page 1 of 4]
Pathologi
Assistant
Attending
Ordering
Copies To
=====

DIAGNOSIS

-Mullerian

cystic features, high grade involving: solid, papillary serous, and

- both ovaries
- lower uterine segment serosa
- omentum (900 grams)
- cul de sac
- tissue submitted as "splenic tumor"
- Lymph/vascular invasion by tumor identified
- Focal tumor necrosis
- See comment and microscopic

-Additional diagnoses

- Benign endometrium and endometrial polyp
- Benign endocervical polyp
- Uterine leiomyoma (subserosal, 1.4 cm)
- Focal superficial adenomyosis
- Omentitis and focal reactive mesothelial cell hyperplasia
- Serosal adhesions with focal mesothelial hyperplasia, appendix, uterus, omentum
- Fibrous obliteration, distal appendiceal lumen
- Fallopian tubes without significant histologic findings

Comment: Histologic features and distribution of the tumor are consistent with ovarian primaries.

=====

HISTORY: Peritoneal carcinoma

MICROSCOPIC:

Tumor: Tumor occupies large portions of both ovaries and the omentum as well as large portions of almost all of the tumor containing sections submitted from the other sites. Tumor also extensively involves the lower uterine segment serosa without apparent invasion into the myometrium. In these sections the tumor growth pattern is predominantly solid with cystic and papillary areas present in several sections and a minor component of gland forming tumor also represented. Tumor nuclei are large and nucleolated, mitoses are frequent, and in some areas there are bizarre tumor giant cells (e.g. H, I). Tumor necrosis (focally with calcification) is noted and there is also tumor-associated desmoplasia, hemorrhage, and inflammation. Spleen is not present in tissue submitted as "splenic tumor".

[page 2 of 4]
Uterus: The myoma is sharply circumscribed and shows the usual spindle pattern with some hyalinization. There is no evidence of significant nuclear atypia, increased mitotic activity, hemorrhage, necrosis, or calcification. No atypical features are seen in sections of the endometrium or the endometrial polyp. There is ciliated/ tubal metaplasia in some endometrial glands and in the lower uterine segment. Focal recent hemorrhage, hemosiderin, and associated histiocytes are noted in the region of the endocervical polyp and in the superficial cervical stroma (P,Q) (previous instrumentation?). Mucus filled cystic glands are also present in the cervix.

Appendix: Proximally the lumen is patent. No carcinoma is seen in the original or steps [REDACTED] of sections from the appendix.

GROSS:

1: SPLENIC TUMOR

Labeled "splenic tumor" and received in formalin is a portion of severely cauterized tissue measuring 1.7 x 0.9 x 0.5 cm. The specimen is bisected and entirely submitted.

A. 2

2: OMENTUM

Labeled "omentum" and received in formalin is a 32 x 21 x 4.5 cm portion of omentum that weighs 900 grams. More than 80% of omentum is infiltrated by tan-white to grey tumor nodules that range from 0.5 to 9 cm and small clear fluid filled smooth lined cysts that range from 1.0 cm to 2.5 cm in greatest dimension. Representative sections are submitted.

B,C. Solid tumor - each

D,E. Cystic tumor - 1 each

3: APPENDIX

Labeled "appendix" and received in formalin is a vermiform appendix measuring 3.5 x 0.6 x 0.5 cm with attached fat measuring 3.5 x 1.7 x 1.0 cm. The serosal surface of the appendix is tan-grey, smooth and shiny with a 0.2 cm tan-white possible nodule 0.8 cm from the tip. The appendiceal wall averages 0.15 cm in thickness and the lumen is less than 0.1 cm in diameter. Representative sections.

F. Proximal, mid portion, tip, and section with possible nodule - 4

4: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin are six pieces of tan-brown to tan-red tissue from 2.0 to 5.0 cm in greatest dimension, largely replaced by firm tumor nodules, some friable, ranging 0.5 to 2.5 cm in greatest dimension. A 1.5 x 1.0 x 0.7 cm smooth lined clear fluid filled cyst is also present. Representative sections are submitted.

G,H. 3 each

5: RIGHT ADNEXA

Labeled "right adnexa" and received in formalin is an ovary measuring 5.5 x 3.8 x 3.5 cm that is essentially replaced by multiple solid tumor nodules from 0.5 to 2.8 cm and multiple cysts from 0.6 to 3.2 cm. The nodules have tan-white cut surfaces with foci of necrosis and hemorrhage. One of the nodules has a papillary appearance on section and a central cavity. The cysts have smooth

[page 3 of 4]
linings and are filled with clear fluid. The attached tube with fimbria measures 4.5 x 1.0 cm. The tubal serosa is smooth without gross tumor and on section no tumor is identified within the wall or lumen of the fallopian tube. Representative sections are submitted.

- I. Solid tumor/ovarian surface - 2
- G. Solid tumor with adjacent cyst - 1
- K. Tumor with papillary structure - 1
- L. Fallopian tube - 2

6: LEFT ADNEXA

Labeled "left adnexa" and received in formalin is a 3.8 x 2.3 x 1.8 cm ovary. The serosal surface is tan-grey to tan-red and has multiple tan-grey tumor nodules from 0.2 to 1.2 cm on its surface. The entire ovary is replaced by solid tumor nodules up to 1.6 cm and cysts, the largest measuring 1.6 cm and showing minimal blood clot adherent to its lining. A 1.6 cm firm, nodule arises from the cyst lining and protrudes into the cyst lumen. A 6.5 x 4.5 cm broad ligament with multiple tan- white to tan- grey tumor nodules ranging from 0.2 to 2.3 cm, some solid and some friable with papillary appearance is attached to the ovary and tube. The fallopian tube with fimbria is 4.0 cm long. The serosal surface of the fallopian tube is smooth without gross tumor. The tube wall is 0.2 cm in thickness, the lumen is 0.1 cm in diameter; no tumor is seen in the tube lumen or wall. Representative sections are submitted.

- M. Left fallopian tube - 2
- N. Tumor nodules and cysts, ovary - 2
- O. Tumor nodules, ligament - 3

7: UTERUS

Labeled "uterus" and received in formalin is a previously opened uterus measuring 7.7 cm from fundus to cervix, 5 cm from cornu to cornu and 4.0 cm from anterior to posterior serosa. The specimen weighs 110 grams. The serosal surface is tan-pink and smooth in the region of the fundus. There is some tumor involving the lower uterine segment serosa anteriorly and extensive (approximating 6.8 x 4.3 x 1.5 cm) tumor with papillary appearance involving the lower uterine segment serosa posteriorly. A subserosal myoma, 1.4 cm in greatest dimension, is present near the left cornu. The endocervical canal measures 1.7 cm in length and 0.4 cm in width. Posteriorly there is a 1.0 x 0.2 x 0.2 cm soft endocervical polyp. The endometrial cavity measures 2.5 cm in length and 1.5 cm in width. The endometrium is 0.1 cm thick with a 1.7 x 0.7 x 0.3 cm soft polyp on the posterior wall. The myometrium is 1.5 cm in thickness. Representative sections are submitted.

- P. Anterior cervix - 1
- Q. Posterior cervix with polyp - 1
- R. Anterior lower uterine segment - 1
- S. Posterior lower uterine segment - 1
- T. Posterior endometrium with polyp - 1
- U. Posterior endometrium - 1
- V. Anterior endometrium - 2
- W. Leiomyoma - 1
- X,Y. Posterior serosal tumor implant - 1 each
- V. Anterior serosal tumor implant - 1

[page 4 of 4]
[REDACTED]

I [REDACTED] the pathologist of record, have personally examined the specimen, interpreted the results, reviewed this report and signed it electronically.

[REDACTED]

Confidentiality Warning: The information in this system should only be viewed by physicians and other patient care personnel with a "need to know" for purposes of diagnosis and treatment. All accesses are logged with your name, the patient's name, the type of data viewed, the date and time. Inappropriate accesses are subject to disciplinary measures and/or legal action, up to and including termination of employment on the first offense.

This viewing system is not the official medical record. Any printouts from this system should be disposed of properly and should not be filed or placed in a patient chart.

Source: NCI Genomic Data Commons file 62319eb3-e035-4c68-a36e-e6da733f62f2 (TCGA-23-2079.66ACE408-FC31-463B-A218-94FDEF0AFAAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).